Gene-level copy-number profile of tumor specimen ALCH-B3G7-TTP1-A from ALCHEMIST case ALCH-B3G7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.4 years (25,718 days).
Specimen ALCH-B3G7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4be07e6b-e6c9-4a67-85e5-d3cdd6a64042.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3G7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/9ce33e14-c33e-4d91-8a2a-20e521e9092f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 109; copy number 2: 54,273; copy number 3: 3,660; copy number 4: 238; copy number 5: 17; copy number 7: 13; copy number 8: 36; copy number 10: 47.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,309,230–90,315,836, 2 genes: AC233263.2, IGKV1OR2-118.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 113 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:752,579–991,190, 5 genes, copy number 8 (within-gene range 2–8): WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr12:23,529,504–29,381,189, 107 genes, copy number 5–10 (broad region; genes not listed).
- chr16:33,808,778–33,810,767, 1 gene, copy number 7: AC136428.3.

Autosomal genes at a single copy (total copy number 1): 68. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
